Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6400, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6400-01A (Primary Tumor).

[page 1 of 2]
TCGA-DU-6400

AGE/SEX: [REDACTED]

DOB: [REDACTED]

SURGERY DATE: [REDACTED]

RECEIVE DATE: [REDACTED]

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSIES: OLIGODENDROGLIOMA.
B. BRAIN, LEFT TEMPORAL, EXCISIONAL BIOPSIES: OLIGODENDROGLIOMA
WITH ATYPICAL FEATURES. MIB-1 LABELLING INDEX 0.5%.
SEE MICROSCOPIC AND COMMENT.
-

Operation/Specimen: Brain, left temporal.

Clinical History and Pre-Op Dx: [REDACTED] with difficulty with speech and decreased short term memory. Has non-enhancing, multicystic, large tumor in the left temporal lobe.

GROSS PATHOLOGY: A. Received fresh, three fragments, 0.6 cm. in aggregate. Glassy, pinkish-white and soft. In toto #1 and 2. Tissue fixed in glutaraldehyde.

INTRAOPERATIVE CONSULTATION: Brain, left temporal: Glial neoplasm, possibly oligodendroglioma.

B.

SPECIMEN: Tumor.

FIXATIVE: Unfixed.

GENERAL: 2.2 X 2.0 X 0.3 cm. aggregate of mottled, tan red soft tissue, specimen divided and all submitted.

SECTIONS: All submitted, X1 and X2.
[REDACTED]

MICROSCOPIC: A. Portions of neoplastic glial proliferation made up of primarily round, hyperchromatic nuclei with perinuclear halos. Focally, the tumor is sparsely cellular and has numerous microvascular calcospherites. In other areas, the tumor is more cellular, appears to be infiltrating gray matter, and has a fibrillary background with gliofibrillary and minigemistocytic cells, or a mucinous change. Fine capillary vessels without cellular proliferation are present. Mitoses are difficult to be found. Nuclear pleomorphism is slight, and necrosis is absent.

B. Portions of brain with a tumor similar to that in part A. In here, areas of sparsely cellular tumor with frequent microcalcification

[page 2 of 2]
intermingle with areas of classical oligodendroglioma (chicken wire and fried egg morphology). However, there also are focal small areas that are hypercellular and less differentiated, with apoptotic cells.

SPECIAL STAINS: Immunoperoxidase methods for GFAP, MIB1 and synaptophysin are performed on block - 2x. In the more cellular areas a MIB-1 labelling index of 0.5% is determined. The GFAP highlights the areas with glial fibrillary background. The synaptophysin reflects the synaptophysin rich background of the infiltrated grey matter.

COMMENT: The tumor, overall, is an oligodendroglioma. It has focal areas with astrocyte phenotype, and loose areas with a mucinous background. In part B, particularly, there are focal areas with prominent hypercellularity. However, mitotic figures are absent, and the MIB-1 is very low at 0.5%. The tumor may be classified as a grade B of Smith's (no vascular changes); however, tumors with hypercellular areas have been referred to as "intermediate" (between low and high grade oligodendrogliomas).

Source: NCI Genomic Data Commons file a5430595-0ac3-42e8-ad37-399ca80477ee (TCGA-DU-6400.A61BE291-6258-47F2-8404-18615093F168.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).